Somatic mutation profile of tumor specimen TARGET-30-PATDXG-01A (aliquot TARGET-30-PATDXG-01A-01D) from TARGET case TARGET-30-PATDXG, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.9 years (688 days).
Specimen TARGET-30-PATDXG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79ea17f0-34c8-46ab-9061-f50658d23f0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATDXG-10A (Blood Derived Normal), aliquot TARGET-30-PATDXG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ba67034-c5b9-44d7-b868-5499b5a2670a

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A1 | c.2320C>A p.P774T | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56807709; called by muse, mutect2, varscan2
- DEDD | c.440C>A p.P147H | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.243); catalogued as COSV63502371; called by muse, mutect2, varscan2
- GDF3 | c.590A>T p.N197I | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61713185; called by muse, mutect2, varscan2
- MSLNL | c.356T>G p.L119R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53504388; called by muse, mutect2, varscan2
- PAX6 | c.379C>A p.L127I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as CD045109, COSV53794772; called by muse, mutect2, varscan2
- PKM | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs751885485, COSV58790471; called by muse, mutect2, varscan2
- PLOD2 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51467040, COSV99283346; called by muse, mutect2, varscan2
- SEC14L5 | c.1612T>A p.W538R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52040164; called by muse, mutect2
- SOX6 | c.2034C>A p.S678R (on ENST00000528429 / NM_001145819.2; = p.S651R on NM_017508.3) | Missense Mutation (SNP) | VAF 61/98 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV57052219; called by muse, mutect2, varscan2
- ABCA10 | c.3022C>A p.L1008I | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.05); called by muse, mutect2
- RPTN | c.106C>A p.L36M | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MOGAT3 | c.843G>T p.L281= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV56175826; called by muse, mutect2, varscan2
- PLCG2 | c.1710C>A p.P570= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV63872994; called by muse, mutect2, varscan2
- TFEC | c.960T>A p.P320= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV55404031; called by muse, mutect2, varscan2
